Gene-level copy-number profile of tumor specimen TARGET-20-PANVGP-04A from TARGET case TARGET-20-PANVGP, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.6 years (4,950 days).
Specimen TARGET-20-PANVGP-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-AML.301985ff-8edc-5b2c-893b-fd344f33bfca.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-20-PANVGP-14A (bone marrow normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 388 have no estimate.
https://portal.gdc.cancer.gov/files/f60c4fd4-d7b5-4502-85b9-f9c38a3b5f90

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,078; copy number 2: 55,469; copy number 3: 686; copy number 4: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,697. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
